Somatic mutation profile of tumor specimen TCGA-BR-6802-01A (aliquot TCGA-BR-6802-01A-11D-1882-08) from TCGA case TCGA-BR-6802, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.5 years (23,915 days).
Specimen TCGA-BR-6802-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 833fdd23-1445-42a1-9ce4-047997e81ecf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6802-10A (Blood Derived Normal), aliquot TCGA-BR-6802-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aafd923e-2651-4260-a5f1-b2d2c3629243

The open-access MAF lists 516 somatic variants for this specimen: 386 protein-altering or splice-affecting, 119 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 119, Frame Shift Del 78, Frame Shift Ins 19, Nonsense Mutation 18, Splice Site 7, Intron 6, RNA 3, Splice Region 2, In Frame Del 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5318C>T p.A1773V | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs760549861, CM087708, CM1210213, COSV64670966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | hotspot (GDC flag); catalogued as COSV61371666; called by muse, mutect2
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 15/131 reads (11%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- BCL11A | c.691dup p.L231Pfs*3 (on ENST00000335712 / NM_001365609.1; = p.L265Pfs*3 on NM_018014.4) | Frame Shift Ins (INS) | VAF 12/92 reads (13%) | catalogued as rs761909641; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- MLH1 | c.588del p.K196Nfs*6 | Frame Shift Del (DEL) | VAF 52/425 reads (12%) | catalogued as rs63751653, CM151408, COSV51624461; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 28/156 reads (18%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 6/32 reads (19%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 13/106 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 90/279 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV69041520, COSV69042084; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 30/252 reads (12%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCC9 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200891785, CM141607, COSV53961570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 18/134 reads (13%) | catalogued as rs1560546604; called by mutect2, pindel, varscan2
- ADAMTS4 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200258484, COSV63489302; called by muse, mutect2, varscan2
- ADAMTS9 | c.4995del p.S1666Vfs*7 | Frame Shift Del (DEL) | VAF 14/137 reads (10%) | catalogued as rs754786025; called by mutect2, pindel, varscan2
- ADGRD1 | c.896A>G p.Y299C | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV55438721; called by muse, mutect2
- ADGRE1 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200264142, COSV51671907; called by muse, mutect2, varscan2
- ADGRF1 | c.1470T>G p.I490M | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV51943860; called by muse, mutect2, varscan2
- ADGRG4 | c.8874del p.F2958Lfs*6 | Frame Shift Del (DEL) | VAF 44/211 reads (21%) | catalogued as rs771931957; called by mutect2, pindel, varscan2
- ADGRL3 | c.2812G>T p.D938Y (on ENST00000506720 / NM_001322402.2; = p.D870Y on NM_015236.6) | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV72229249; called by muse, mutect2, varscan2
- ADGRV1 | c.12896G>A p.R4299Q | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.136); catalogued as rs767181564, COSV67978320; called by muse, mutect2, varscan2
- AGRN | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754169694, COSV65067703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK3 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs188377589, COSV63346282; called by muse, mutect2
- AKAP13 | c.5870A>G p.E1957G (on ENST00000394518 / NM_007200.5; = p.E1961G on NM_006738.6) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63448114; called by muse, mutect2, varscan2
- AMPD2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs751988000, COSV56646182; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 20/141 reads (14%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.4619G>A p.S1540N | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as COSV51840437; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6514G>T p.G2172C | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV51840452; called by muse, mutect2, varscan2
- ANKRD36 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101347287, COSV70743664; called by muse, mutect2
- ARHGEF10L | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 31/159 reads (19%) | catalogued as COSV51427611; called by muse, mutect2, varscan2
- ARHGEF15 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.384); catalogued as rs766415435, COSV62724296; called by muse, mutect2, varscan2
- ARMC3 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53057018; called by muse, mutect2, varscan2
- ARNTL | c.851G>T p.S284I (on ENST00000403290 / NM_001297719.2; = p.S283I on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV62985155; called by muse, mutect2, varscan2
- ATP10D | c.4099T>A p.S1367T | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV56685966; called by muse, mutect2, varscan2
- ATP2C2 | c.1711C>A p.L571I | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV52292727; called by muse, mutect2, varscan2
- AVPR1A | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs779030335, COSV54545609; called by muse, mutect2, varscan2
- BCAM | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs956006521, COSV54300577; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 40/89 reads (45%) | catalogued as rs768244116; called by mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as rs752427670; called by mutect2, varscan2
- BMP2K | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs752366508, COSV55008423; called by muse, mutect2, varscan2
- BMS1 | c.1373A>C p.N458T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV65732853; called by muse, mutect2, varscan2
- BPGM | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs141221644; called by muse, mutect2, varscan2
- BUB3 | c.631A>C p.S211R | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV64363502; called by muse, mutect2
- C10orf90 | c.449del p.P150Qfs*58 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | catalogued as rs762432781; called by mutect2, pindel, varscan2
- CACNA1D | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs755537392, COSV55437298; called by muse, mutect2, varscan2
- CASK | c.2734C>T p.L912F (on ENST00000378163 / NM_001367721.1; = p.L907F on NM_003688.3) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs777220099, COSV59361392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 19/96 reads (20%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC30 | c.2347G>A p.A783T (on ENST00000340612; = p.A740T on NM_001080850.3) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV59245672; called by muse, mutect2, varscan2
- CCDC80 | c.2600T>G p.L867R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52814875; called by muse, mutect2, varscan2
- CCL23 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs768484405; called by muse, mutect2
- CCNT1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 66/424 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as COSV56063163; called by muse, mutect2, varscan2
- CD163L1 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58010875; called by muse, mutect2
- CD4 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.389); catalogued as COSV50589078; called by muse, mutect2, varscan2
- CDH18 | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV56901168, COSV99935124; called by muse, mutect2
- CDX4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs760648974, COSV65171429; called by muse, mutect2, varscan2
- CEP192 | c.4978G>A p.A1660T | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.244); catalogued as COSV58059767; called by muse, mutect2
- CHD9 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs147266259, COSV68297015; called by muse, mutect2, varscan2
- CHRNG | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs1363680367, COSV67315239; called by muse, mutect2, varscan2
- CHST2 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs559583916, COSV58884701; called by muse, mutect2, varscan2
- CIB3 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54165401; called by muse, mutect2
- CILP | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 24/121 reads (20%) | catalogued as rs150946463; called by muse, mutect2, varscan2
- CIP2A | c.780T>A p.D260E | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV55417054; called by muse, mutect2, varscan2
- CLIC5 | c.731T>C p.V244A (on ENST00000185206 / NM_001370649.1; = p.V85A on NM_016929.5) | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV51755114, COSV51759604; called by muse, mutect2, varscan2
- CNTN3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs569008734, COSV55162972; called by muse, mutect2, varscan2
- COL6A1 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as rs566453317, COSV62611451; called by muse, mutect2, varscan2
- COL7A1 | c.8734T>C p.C2912R | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56475973; called by muse, mutect2, varscan2
- COX4I1 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53665572; called by muse, mutect2
- CPS1 | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51801883; called by muse, mutect2
- CR1 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV65455769; called by muse, mutect2, varscan2
- CTLA4 | c.529del p.Y177Ifs*10 | Frame Shift Del (DEL) | VAF 34/296 reads (11%) | catalogued as COSV55593336; called by mutect2, pindel
- CTSF | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV59747388; called by muse, mutect2, varscan2
- CUBN | c.9350G>A p.R3117H | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs184750323, COSV64707712; called by muse, mutect2
- CYP2C18 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV53669622; called by muse, mutect2, varscan2
- CYP4Z1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs748235991, COSV61963750; called by mutect2, varscan2
- DCLRE1A | c.1038del p.K346Nfs*7 | Frame Shift Del (DEL) | VAF 22/146 reads (15%) | catalogued as rs1405598603; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | catalogued as rs766714372; called by mutect2, varscan2
- DIP2C | c.1578G>T p.Q526H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as COSV55145673; called by muse, mutect2, varscan2
- DLGAP4 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs865912625, COSV59414343; called by muse, mutect2, varscan2
- DNAH2 | c.9087G>T p.E3029D | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV66716252; called by muse, mutect2, varscan2
- DNAJC2 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50785496; called by muse, mutect2, varscan2
- DNAJC5B | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52535695, COSV99395865; called by muse, mutect2, varscan2
- DOCK2 | c.2305T>A p.S769T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV56941628; called by muse, varscan2
- DOCK3 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56502491; called by muse, mutect2, varscan2
- DOCK9 | c.6016C>T p.R2006* (on ENST00000376460 / NM_001366676.2; = p.R2007* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV59619379; called by muse, mutect2, varscan2
- DOK6 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779449377, COSV66926062; called by muse, mutect2
- DOP1B | c.6843A>T p.L2281F | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs758288400, COSV67690560; called by muse, mutect2
- DPEP3 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV52050308; called by muse, mutect2, varscan2
- DSPP | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.031); catalogued as COSV56807739; called by muse, mutect2, varscan2
- DUS2 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV62707840; called by muse, mutect2, varscan2
- DYRK1A | c.732C>G p.N244K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58292311; called by muse, mutect2, varscan2
- E2F8 | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV51461727, COSV51462894; called by muse, mutect2, varscan2
- ECEL1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.34); catalogued as rs765412064, COSV58811170; called by muse, varscan2
- ECRG4 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs867836258, COSV52999871; called by muse, mutect2
- EFEMP2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57258879; called by muse, mutect2
- EIF4G1 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV59989016; called by muse, mutect2, varscan2
- EIF4G1 | c.3268C>T p.R1090* (on ENST00000346169 / NM_198241.3; = p.R895* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | catalogued as COSV59989031; called by muse, mutect2, varscan2
- ELK3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs751599496, COSV57385517, COSV57387771; called by muse, mutect2
- ELMO2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs562401369, COSV51681269; called by muse, mutect2, varscan2
- ELP1 | c.607dup p.D203Gfs*33 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | catalogued as rs752490541; called by pindel, varscan2
- ENPP4 | c.628del p.I210* | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | catalogued as rs756006851; called by mutect2, pindel, varscan2
- ENTPD7 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs555052941, COSV65111920; called by muse, mutect2, varscan2
- EPHA3 | c.1938del p.E647Rfs*9 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | catalogued as rs1467832547; called by mutect2, pindel, varscan2
- EPHA6 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.019); catalogued as rs1462512020, COSV67558572; called by muse, mutect2
- EPHB6 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752688738, COSV63890450, COSV63890523; called by mutect2, varscan2
- ERC2 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs769101058, COSV55600221; called by muse, mutect2, varscan2
- ESYT2 | c.1135C>T p.R379W (on ENST00000613624; = p.R303W on NM_020728.3) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772699152, COSV51747637; called by muse, mutect2, varscan2
- EZHIP | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs377315415, COSV100539551; called by muse, mutect2
- F13A1 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs767046666, COSV53553269, COSV99344063; called by muse, varscan2
- F13B | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as rs1382600973, COSV66372176; called by muse, mutect2, varscan2
- F2RL2 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56969800; called by muse, mutect2, varscan2
- F7 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749928438, COSV60644949; called by muse, mutect2, varscan2
- FAM210A | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59183445; called by muse, mutect2, varscan2
- FBXO11 | c.1877G>A p.S626N (on ENST00000403359 / NM_001190274.2; = p.S542N on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV57016035, COSV57019259; called by muse, mutect2, varscan2
- FBXO38 | c.1738+1G>A p.X580_splice | Splice Site (SNP) | VAF 14/88 reads (16%) | catalogued as COSV57025761, COSV57031810; called by muse, mutect2, varscan2
- FBXO41 | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.331); catalogued as COSV54581753; called by muse, mutect2
- FCGBP | c.59T>C p.L20S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs751978881; called by muse, mutect2, varscan2
- FEM1B | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60987733; called by muse, mutect2, varscan2
- FGD2 | c.962T>A p.L321H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51462246; called by muse, mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | catalogued as rs1216734611; called by mutect2, pindel, varscan2
- FLG | c.3403A>G p.R1135G | Missense Mutation (SNP) | VAF 74/500 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372726892, COSV64236302; called by muse, mutect2, varscan2
- FLG | c.3192G>A p.W1064* | Nonsense Mutation (SNP) | VAF 158/981 reads (16%) | catalogued as rs755119896, COSV64236309; called by muse, mutect2
- FLRT1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); catalogued as rs1163223569, COSV55356757; called by muse, mutect2, varscan2
- FPGS | c.1287+2T>C p.X429_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as rs1440652810, COSV100785250; called by muse, mutect2, varscan2
- FREM1 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as rs369918312; called by muse, mutect2, varscan2
- FRYL | c.5518C>G p.L1840V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV51939501; called by muse, mutect2
- FUT9 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as COSV56142295, COSV56158434; called by muse, mutect2, varscan2
- GALNT15 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV60215281; called by muse, mutect2, varscan2
- GALR1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV55315823; called by muse, mutect2
- GEMIN7 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1568434086, COSV54319148; called by muse, mutect2, varscan2
- GFOD1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64953040; called by muse, mutect2
- GOLGA1 | c.2136G>T p.E712D | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52346388; called by muse, mutect2, varscan2
- GOLT1B | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV57552982; called by muse, mutect2, varscan2
- GPCPD1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1464554250, COSV66830136; called by muse, mutect2, varscan2
- GPD1L | c.504C>T p.I168= | Splice Region (SNP) | VAF 18/170 reads (11%) | catalogued as rs139369157, COSV56988878; called by muse, mutect2, varscan2
- GREB1 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 53/490 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376668046, COSV52179909; called by muse, mutect2, varscan2
- GRXCR1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 38/664 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.089); catalogued as rs370812791, COSV67670026; called by muse, mutect2
- GXYLT1 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55132360; called by muse, mutect2, varscan2
- HAPLN3 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV62084277; called by muse, mutect2
- HDAC6 | c.3098dup p.T1034Nfs*55 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs781824028; called by mutect2, varscan2
- HHLA2 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63315575; called by muse, mutect2
- HIVEP1 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774414691, COSV65098640; called by muse, mutect2, varscan2
- HLA-DPB1 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV69602282; called by muse, mutect2, varscan2
- HTRA2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1251760357, COSV51206123; called by muse, mutect2, varscan2
- IBTK | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60390834, COSV60392717; called by muse, mutect2, varscan2
- IFNA7 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.789); catalogued as rs761549500, COSV53330458; called by muse, mutect2, varscan2
- IPO13 | c.2302T>A p.F768I | Missense Mutation (SNP) | VAF 76/534 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV64892875; called by muse, mutect2, varscan2
- ITGA8 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65224453; called by muse, mutect2, varscan2
- ITGB1 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478983; called by muse, mutect2, varscan2
- ITGB2 | c.2035A>C p.N679H (on ENST00000302347; = p.N655H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV56607671; called by muse, mutect2, varscan2
- ITPR3 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs369824854; called by muse, mutect2, varscan2
- KAT2B | c.430+2T>C p.X144_splice | Splice Site (SNP) | VAF 35/223 reads (16%) | catalogued as COSV55426482; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNT1 | c.760A>G p.I254V (on ENST00000488444; = p.I273V on NM_020822.3) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1220559272, COSV53695329; called by muse, mutect2, varscan2
- KDM6B | c.3580C>T p.R1194W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54677744; called by muse, mutect2, varscan2
- KIF16B | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV61701237; called by muse, mutect2
- KRBA1 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765373207, COSV55439884; called by muse, mutect2, varscan2
- KRT32 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs149170177; called by muse, mutect2, varscan2
- KRT79 | c.642del p.R215Gfs*58 | Frame Shift Del (DEL) | VAF 25/203 reads (12%) | catalogued as rs1346341380, COSV57939480; called by mutect2, pindel, varscan2
- LAMB1 | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs767881160, COSV55961529; called by muse, mutect2, varscan2
- LCOR | c.2643G>T p.E881D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV53714344; called by muse, mutect2, varscan2
- LEMD3 | c.1626A>G p.A542= | Splice Region (SNP) | VAF 8/85 reads (9%) | catalogued as COSV57648405; called by muse, mutect2
- LGALSL | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53230006; called by muse, mutect2, varscan2
- LGR5 | c.1928del p.L643Cfs*24 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | catalogued as rs753933845; called by mutect2, pindel, varscan2
- LMF2 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774847016, COSV53316114; called by muse, mutect2, varscan2
- LPCAT1 | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV52035555; called by muse, mutect2, varscan2
- LRP2 | c.3209C>T p.S1070L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs745389472, COSV55540626; called by muse, mutect2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRCC1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765839225, COSV64482561; called by muse, mutect2, varscan2
- LRRK2 | c.2221G>T p.G741* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | catalogued as COSV54143703; called by muse, mutect2, varscan2
- LVRN | c.1994T>C p.L665S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.871); catalogued as COSV63495925; called by muse, mutect2, varscan2
- MACC1 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1224151317, COSV60540772; called by muse, mutect2, varscan2
- MAN2A2 | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV64637180; called by muse, mutect2, varscan2
- MAP3K19 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs372912449; called by muse, mutect2, varscan2
- MDC1 | c.5798G>A p.R1933Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs536243116, COSV64523145; called by muse, mutect2, varscan2
- MED21 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.587); catalogued as COSV51460624; called by muse, mutect2, varscan2
- MFSD12 | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV61534811; called by muse, mutect2, varscan2
- MLYCD | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV52304066; called by muse, mutect2
- MOGS | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV51968099; called by muse, mutect2
- MPST | c.529C>T p.R177C (on ENST00000341116 / NM_001369904.2; = p.R197C on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs1197851573, COSV62017158; called by muse, mutect2, varscan2
- MRAP | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57936271; called by muse, mutect2, varscan2
- MREG | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs543536857, COSV54372725; called by muse, mutect2, varscan2
- MSANTD4 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 13/197 reads (7%) | catalogued as rs768814726, COSV57285120; called by muse, mutect2
- MTSS1 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV52674238; called by muse, mutect2
- MTSS2 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV58697389; called by muse, mutect2, varscan2
- MUC16 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as rs573130776, COSV67444251, COSV67458207; called by muse, mutect2, varscan2
- MUC4 | c.15425A>G p.Q5142R (on ENST00000463781 / NM_018406.7; = p.Q906R on NM_004532.6) | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs771793916, COSV57765073; called by muse, mutect2
- MUSK | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs776795823, COSV51877981; called by muse, mutect2, varscan2
- MYCBPAP | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV60405383; called by muse, mutect2, varscan2
- NAT10 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57662347; called by muse, mutect2, varscan2
- NCOA2 | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1239203922, COSV71763363, COSV71764438; called by muse, mutect2
- NEK6 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57215915; called by muse, mutect2, varscan2
- NIPBL | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56942107; called by muse, mutect2, varscan2
- NKAIN1 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs760331473, COSV55273787; called by muse, mutect2, varscan2
- NLRP5 | c.2050A>C p.T684P | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV66762004; called by muse, varscan2
- NR1H2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs770846079, COSV53799852; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | catalogued as rs774343392; called by mutect2, varscan2
- NRP1 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV55159730; called by muse, mutect2
- NRXN2 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769291803, COSV55447013; called by muse, mutect2, varscan2
- NTF3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV58417146; called by muse, mutect2, varscan2
- NTNG1 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53962679; called by muse, mutect2, varscan2
- NUP155 | c.2309C>A p.A770D (on ENST00000231498 / NM_153485.3; = p.A711D on NM_004298.4) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51526738; called by muse, mutect2
- OR2AG1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.35); catalogued as COSV56625317; called by muse, mutect2
- OR2T12 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs928256869, COSV58776030, COSV58777989; called by muse, mutect2, varscan2
- OR2T34 | c.350T>G p.V117G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV60899567; called by mutect2, varscan2
- OR51F2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.053); catalogued as rs189883409, COSV59063678; called by muse, mutect2, varscan2
- OR5AC2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs565646972, COSV62279069; called by muse, mutect2, varscan2
- OR5H1 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 50/521 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV100641622, COSV100641641; called by muse, mutect2, varscan2
- OR8G1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100422294; called by muse, mutect2, varscan2
- PAPOLB | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as COSV68199129; called by muse, mutect2, varscan2
- PCDHB6 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV50689744; called by muse, mutect2, varscan2
- PDZRN3 | c.1751C>A p.S584* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV55191079; called by muse, mutect2, varscan2
- PER3 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1049433732, COSV62704265; called by muse, mutect2
- PHLDB1 | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs137998974; called by muse, mutect2, varscan2
- PIGA | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1569179995, COSV61236830; ClinVar: uncertain significance; called by muse, mutect2
- PIK3R2 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55846675, COSV55847040; called by muse, mutect2, varscan2
- PLIN4 | c.3779G>A p.C1260Y (on ENST00000301286; = p.C1275Y on NM_001367868.2) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV56681241; called by muse, mutect2, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | catalogued as rs751873496; called by mutect2, varscan2
- PMFBP1 | c.2593G>A p.D865N (on ENST00000537465; = p.D860N on NM_031293.3) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV52820613, COSV52826991; called by muse, mutect2, varscan2
- PML | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV51441957; called by muse, mutect2, varscan2
- PNPLA6 | c.1363G>A p.G455R (on ENST00000414982 / NM_001166111.2; = p.G407R on NM_006702.5) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.358); catalogued as rs573529919, COSV55373526; called by muse, mutect2, varscan2
- POU2F3 | c.725T>C p.M242T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764210023, COSV52792091; called by muse, mutect2, varscan2
- POU4F2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55582860, COSV55584563; called by muse, mutect2, varscan2
- PPFIA4 | c.2273G>A p.G758D (on ENST00000447715; = p.G759D on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55311251; called by muse, mutect2, varscan2
- PPP1R26 | c.594del p.G199Afs*18 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as COSV100778125; called by mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 16/113 reads (14%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PRPF40B | c.1076G>A p.R359H (on ENST00000380281; = p.R353H on NM_012272.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs542656887, COSV56057704; called by muse, mutect2, varscan2
- PTOV1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs750669934, COSV55586198; called by muse, mutect2, varscan2
- PTPDC1 | c.834G>T p.E278D (on ENST00000375360 / NM_177995.3; = p.E330D on NM_152422.4) | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56621200; called by muse, mutect2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- QSOX1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs201825048; called by muse, mutect2, varscan2
- R3HDM1 | c.2632-1G>T p.X878_splice | Splice Site (SNP) | VAF 18/184 reads (10%) | catalogued as COSV51520819; called by muse, mutect2
- RAB11FIP1 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1305713006, COSV99769837; called by muse, mutect2, varscan2
- RALGAPA1 | c.2300C>T p.T767I | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV51876449; called by muse, mutect2, varscan2
- RALGDS | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs143871051; called by muse, mutect2
- RASAL2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752504099, COSV100862458, COSV62709448; called by muse, mutect2, varscan2
- RGS22 | c.2812T>G p.W938G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV62656988, COSV62657161; called by muse, mutect2
- RGS22 | c.162del p.F54Lfs*3 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as COSV62660466; called by mutect2, pindel, varscan2
- RGS6 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1261035708, COSV59564231, COSV59577782; called by muse, mutect2, varscan2
- RHPN1 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs374426571; called by muse, mutect2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RNF122 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56358828; called by muse, mutect2
- RNF19B | c.1258A>G p.S420G | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV52386736; called by muse, mutect2, varscan2
- RPL14 | c.105+2T>C p.X35_splice | Splice Site (SNP) | VAF 17/109 reads (16%) | catalogued as COSV59082340; called by muse, mutect2, varscan2
- RPLP0 | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs755528442, COSV56103483; called by muse, mutect2, varscan2
- RPUSD1 | c.410-1G>T p.X137_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | catalogued as COSV50099711; called by muse, mutect2, varscan2
- RSPH1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); catalogued as COSV52318293; called by muse, mutect2, varscan2
- RTL5 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV65452362; called by muse, mutect2, varscan2
- RXFP3 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV57504015; called by muse, mutect2
- SALL3 | c.3706G>A p.G1236S | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201141943, COSV73305752; called by muse, mutect2, varscan2
- SCN5A | c.5132C>T p.A1711V (on ENST00000333535 / NM_198056.3; = p.A1710V on NM_000335.5) | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100347081; called by muse, mutect2
- SEC14L1 | c.439del p.I147Lfs*3 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs34381783; called by mutect2, pindel, varscan2
- SEL1L3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV53536245; called by muse, mutect2, varscan2
- SERTAD4 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65398733; called by muse, mutect2, varscan2
- SIDT1 | c.1046-1G>T p.X349_splice | Splice Site (SNP) | VAF 7/72 reads (10%) | catalogued as COSV53498180; called by muse, mutect2, varscan2
- SIPA1L1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1297221334, COSV62168316; called by muse, mutect2, varscan2
- SLC12A8 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200851560; called by muse, mutect2, varscan2
- SLC17A6 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs760879211, COSV54133395; called by muse, mutect2, varscan2
- SLC35F5 | c.741_742del p.F247Lfs*24 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC38A8 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.237); catalogued as rs775786911, COSV55304336; called by muse, mutect2, varscan2
- SLC66A3 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV54466426; called by muse, mutect2, varscan2
- SOST | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443836437, COSV57012191; called by muse, mutect2, varscan2
- SPIDR | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV52369447; called by muse, mutect2
- SRD5A3 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV51711210; called by muse, mutect2, varscan2
- SSH2 | c.3550G>A p.A1184T | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs144293105; called by muse, mutect2, varscan2
- SSTR1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV57454920; called by muse, mutect2
- STIMATE | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.602); catalogued as rs747879938, COSV61890476; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs747316268, COSV52690552; called by mutect2, pindel, varscan2
- SUV39H1 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61920247; called by muse, mutect2, varscan2
- TACC1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52521385; called by muse, mutect2, varscan2
- TAF3 | c.2585G>A p.G862D | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100719945; called by muse, mutect2
- TBC1D31 | c.1893del p.H632Tfs*8 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs768246273; called by mutect2, varscan2
- TCEAL6 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs781884310, COSV65653780; called by muse, mutect2, varscan2
- TECTA | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50687858; called by muse, mutect2
- THEM4 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs762280726, COSV64294907; called by muse, varscan2
- TIGD3 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs761178054, COSV52887843; called by muse, mutect2, varscan2
- TLN2 | c.5419G>A p.A1807T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV60885462; called by muse, mutect2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMEM132A | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV50000482; called by muse, mutect2, varscan2
- TMEM168 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760899014, COSV57179224; called by muse, mutect2
- TMEM169 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV55264141; called by muse, mutect2, varscan2
- TNFRSF9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs145966863; called by muse, mutect2, varscan2
- TNFSF10 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53842443; called by muse, mutect2, varscan2
- TNRC6A | c.2656G>A p.G886S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs767104641, COSV59361122; called by muse, mutect2, varscan2
- TNS1 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.348); catalogued as COSV50690430; called by muse, mutect2
- TOR1A | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100693899; called by muse, mutect2, varscan2
- TP53BP1 | c.3902A>C p.D1301A | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV55496310; called by muse, mutect2, varscan2
- TP63 | c.1415T>C p.M472T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV53196191; called by muse, mutect2, varscan2
- TRIM26 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as rs765111699, COSV68962835; called by muse, mutect2, varscan2
- TRIP12 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777391885, COSV52259085; called by muse, mutect2, varscan2
- TRMT2B | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58618446; called by muse, mutect2, varscan2
- TRPM4 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as COSV53260140; called by muse, mutect2, varscan2
- TRPM5 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772292156, COSV50144391; called by muse, mutect2, varscan2
- TSKS | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV55872802, COSV55875346; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC30A | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53686103; called by muse, mutect2, varscan2
- TTC6 | c.1181A>G p.H394R (on ENST00000267368; = p.H1760R on NM_001310135.3) | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99941685; called by muse, mutect2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL4 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs377266125; called by muse, mutect2, varscan2
- TTN | c.66256C>T p.P22086S (on ENST00000591111; = p.P14662S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV59884099; called by muse, mutect2, varscan2
- TTN | c.37024A>G p.S12342G (on ENST00000591111; = p.S4918G on NM_003319.4) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | PolyPhen benign (0.053); catalogued as COSV59884158; called by muse, mutect2, varscan2
- TUSC3 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); catalogued as COSV65877588; called by muse, mutect2, varscan2
- TUT7 | c.2842del p.Y948Mfs*16 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs751076382; called by mutect2, varscan2
- UPF3A | c.1225del p.E409Rfs*107 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs1227258446, COSV60895065; called by mutect2, pindel
- UTRN | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as COSV62328563; called by muse, mutect2, varscan2
- VAV3 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV64064981; called by muse, mutect2, varscan2
- VIRMA | c.5417A>G p.H1806R | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52581686; called by muse, mutect2, varscan2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs756149444; called by mutect2, varscan2
- VWA3A | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV55387936; called by muse, mutect2, varscan2
- WAPL | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV53932304; called by muse, mutect2, varscan2
- WDR11 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1481642523, COSV54785336; called by muse, mutect2, varscan2
- WDR37 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs768199735, COSV54126803; called by muse, mutect2, varscan2
- WNK1 | c.5774C>T p.A1925V (on ENST00000315939 / NM_018979.4; = p.A1677V on NM_014823.3) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60025446; called by muse, mutect2, varscan2
- WNK3 | c.2757G>T p.L919F | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV63612074; called by muse, mutect2
- WWP2 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV63122969; called by muse, mutect2, varscan2
- WWTR1 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs377048586; called by muse, mutect2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | catalogued as rs762052135; called by mutect2, varscan2
- Z83844.2 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV100379036; called by mutect2, varscan2
- ZBTB22 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV56466514; called by muse, mutect2, varscan2
- ZIM3 | c.1150dup p.I384Nfs*9 | Frame Shift Ins (INS) | VAF 25/202 reads (12%) | catalogued as rs750173990; called by mutect2, varscan2
- ZNF197 | c.1608del p.K536Nfs*126 | Frame Shift Del (DEL) | VAF 26/211 reads (12%) | catalogued as COSV60360017; called by mutect2, pindel, varscan2
- ZNF292 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV60535521; called by muse, mutect2
- ZNF32 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | catalogued as rs1180506567, COSV65641458; called by muse, mutect2, varscan2
- ZNF462 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as rs749451184, COSV52929649; called by muse, mutect2, varscan2
- ZNF480 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV57994594; called by muse, mutect2, varscan2
- ZNF567 | c.1619A>G p.K540R (on ENST00000536254 / NM_001322913.1; = p.K509R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV62444171; called by muse, mutect2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 29/153 reads (19%) | catalogued as rs782441698; called by mutect2, pindel, varscan2
- ZNF629 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52697379; called by muse, mutect2, varscan2
- ZNF85 | c.152A>C p.D51A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV56020965; called by muse, mutect2, varscan2
- ZNRF3 | c.941G>A p.R314Q (on ENST00000544604 / NM_001206998.2; = p.R214Q on NM_032173.3) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs372481492; called by muse, mutect2, varscan2
- ABCC1 | c.1345dup p.L449Pfs*124 | Frame Shift Ins (INS) | VAF 24/159 reads (15%) | called by mutect2, pindel, varscan2
- ABL2 | c.2508dup p.S837Ifs*55 (on ENST00000502732 / NM_007314.4; = p.S822Ifs*55 on NM_005158.5) | Frame Shift Ins (INS) | VAF 16/142 reads (11%) | called by mutect2, varscan2
- AFTPH | c.257dup p.N86Kfs*3 | Frame Shift Ins (INS) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- APC | c.5390dup p.N1797Kfs*2 | Frame Shift Ins (INS) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- ARHGAP1 | c.709del p.L237Cfs*135 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by mutect2, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- CARS2 | c.952del p.M318Cfs*5 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- CIT | c.5926del p.L1976Wfs*36 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- COL15A1 | c.293dup p.P99Afs*14 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- CTSH | c.875del p.N292Mfs*8 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel
- DENND1C | c.2005dup p.D669Gfs*23 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- DIS3L2 | c.1835del p.P612Rfs*33 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel
- DNAH8 | c.5696_5708del p.E1899Vfs*17 | Frame Shift Del (DEL) | VAF 12/148 reads (8%) | called by mutect2, pindel
- DOLK | c.1387del p.E463Rfs*15 | Frame Shift Del (DEL) | VAF 19/166 reads (11%) | called by mutect2, pindel, varscan2
- EFNB3 | c.658del p.L220Cfs*74 | Frame Shift Del (DEL) | VAF 15/110 reads (14%) | called by mutect2, pindel, varscan2
- F13A1 | c.397del p.A133Pfs*5 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by pindel, varscan2
- GGPS1 | c.735del p.K245Nfs*10 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- H2BC4 | c.210_211del p.F71* | Frame Shift Del (DEL) | VAF 24/244 reads (10%) | called by pindel, varscan2
- HNRNPA2B1 | c.412dup p.I138Nfs*2 (on ENST00000354667 / NM_031243.3; = p.I126Nfs*2 on NM_002137.4) | Frame Shift Ins (INS) | VAF 20/190 reads (11%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- KAZN | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2
- LMTK3 | c.3594del p.K1199Sfs*117 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel, varscan2
- LZTS2 | c.19_20del p.L7Afs*9 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- MMP28 | c.1073A>T p.E358V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.362); called by muse, mutect2
- MPDZ | c.4745del p.K1582Rfs*7 | Frame Shift Del (DEL) | VAF 24/167 reads (14%) | called by mutect2, pindel, varscan2
- NUMA1 | c.4359del p.L1454Wfs*54 | Frame Shift Del (DEL) | VAF 22/188 reads (12%) | called by mutect2, pindel, varscan2
- OPRPN | c.455_457del p.T152del | In Frame Del (DEL) | VAF 12/99 reads (12%) | called by pindel, varscan2
- PCDH11Y | c.2001del p.K667Nfs*9 (on ENST00000400457 / NM_032973.2; = p.K656Nfs*9 on NM_032971.3) | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- PLA2G15 | c.695del p.G232Afs*23 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- PRKDC | c.11450del p.L3817* | Frame Shift Del (DEL) | VAF 11/117 reads (9%) | called by mutect2, pindel
- PTPRJ | c.1846del p.D616Tfs*19 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | called by mutect2, pindel, varscan2
- RABL2B | c.665_667del p.E222del | In Frame Del (DEL) | VAF 14/130 reads (11%) | called by pindel, varscan2
- REV3L | c.4259del p.L1420Cfs*13 | Frame Shift Del (DEL) | VAF 33/218 reads (15%) | called by mutect2, pindel, varscan2
- SASS6 | c.1368del p.K456Nfs*9 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- SCAF4 | c.359del p.N120Mfs*25 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel
- SLC38A1 | c.919del p.M307Cfs*18 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- SMAP2 | c.456del p.K152Nfs*10 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, varscan2
- SOGA3 | c.2835dup p.V946Cfs*28 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- SPIN3 | c.705del p.K235Nfs*21 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- SRF | c.1004dup p.L336Pfs*39 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel, varscan2
- TAF1L | c.2784del p.F928Lfs*13 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- TCF7 | c.463del p.H155Tfs*44 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | called by mutect2, pindel, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 48/124 reads (39%) | called by mutect2, varscan2
- TRIM29 | c.337del p.A113Lfs*146 | Frame Shift Del (DEL) | VAF 52/413 reads (13%) | called by mutect2, pindel, varscan2
- TRUB1 | c.595del p.L199Sfs*5 | Frame Shift Del (DEL) | VAF 38/293 reads (13%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.3423del p.G1142Efs*17 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- USP8 | c.1427dup p.N476Kfs*35 | Frame Shift Ins (INS) | VAF 11/75 reads (15%) | called by mutect2, varscan2
- UTP20 | c.546dup p.L183Tfs*9 | Frame Shift Ins (INS) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- ZBTB49 | c.195del p.H66Tfs*10 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.584del p.K195Rfs*18 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- ZHX2 | c.1800dup p.G601Rfs*71 | Frame Shift Ins (INS) | VAF 10/92 reads (11%) | called by mutect2, pindel
- ZNF131 | c.1158del p.G387Efs*26 (on ENST00000509156 / NM_001330707.2; = p.G353Efs*26 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, varscan2
- ZNF20 | c.1084_1085dup p.E363Lfs*176 | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | called by mutect2, varscan2
- ZNF623 | c.347_348dup p.L117Sfs*3 | Frame Shift Ins (INS) | VAF 22/195 reads (11%) | called by mutect2, varscan2
- ZNF776 | c.366del p.K122Nfs*31 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, varscan2
- ABCC1 | c.3595C>T p.L1199= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV60680185; called by muse, mutect2, varscan2
- ADAMTSL1 | c.423T>C p.G141= | Silent (SNP) | VAF 37/265 reads (14%) | catalogued as COSV52808484; called by muse, mutect2, varscan2
- ADGRF5 | c.2283T>C p.H761= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV51929687; called by muse, mutect2
- AFF1 | c.1899C>T p.G633= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs1365882367, COSV57116583; called by muse, mutect2, varscan2
- ALS2 | c.3645C>T p.S1215= | Silent (SNP) | VAF 23/201 reads (11%) | catalogued as COSV51883995; called by muse, varscan2
- ANKS6 | c.462C>T p.G154= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1227190643, COSV100782240; called by muse, mutect2, varscan2
- ARHGEF15 | c.1122T>G p.P374= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV62724300; called by muse, mutect2, varscan2
- ARHGEF28 | c.4227C>T p.G1409= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55247331; called by muse, mutect2, varscan2
- ATXN7 | c.552A>G p.S184= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV55748037; called by muse, mutect2, varscan2
- B4GALNT4 | c.609T>C p.A203= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV57321468; called by muse, mutect2, varscan2
- C3orf20 | c.828C>T p.S276= | Silent (SNP) | VAF 34/308 reads (11%) | catalogued as rs776170659, COSV53782407; called by muse, mutect2, varscan2
- CARMIL3 | c.2817C>T p.I939= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs944119524, COSV57724683; called by muse, mutect2, varscan2
- CATSPER4 | c.597C>A p.P199= | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as COSV58792251; called by muse, mutect2, varscan2
- CBLN1 | c.216C>T p.H72= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs1376854550, COSV54653355; called by muse, mutect2
- CCDC178 | c.2466G>A p.R822= (on ENST00000383096 / NM_001105528.3; = p.R784= on NM_198995.3) | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV55759158; called by muse, mutect2, varscan2
- CCNF | c.1341C>T p.Y447= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs777340745, COSV53537722; called by muse, mutect2, varscan2
- CDH2 | c.1281T>C p.P427= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs754190682, COSV52271529; called by muse, mutect2, varscan2
- CDRT15 | c.439C>T p.L147= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1192308116, COSV69755304; called by muse, varscan2
- CHEK2 | c.669C>A p.R223= (on ENST00000382580 / NM_001005735.2; = p.R180= on NM_007194.4) | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100101326, COSV60415480; called by muse, mutect2, varscan2
- CIC | c.603G>A p.R201= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV50547054; called by muse, mutect2, varscan2
- CNOT4 | c.1296G>A p.S432= (on ENST00000315544 / NM_001190848.1; = p.S429= on NM_013316.4) | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs374055552, COSV100211943; called by muse, mutect2
- COL1A2 | c.3288C>T p.G1096= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as rs149097024; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPPED1 | c.267C>T p.G89= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs764661639, COSV55495612; called by muse, mutect2, varscan2
- CPZ | c.1335C>T p.N445= (on ENST00000360986 / NM_001014447.3; = p.N434= on NM_003652.3) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs754721390, COSV59921475; called by mutect2, varscan2
- CSMD1 | c.4311C>T p.N1437= (on ENST00000520002; = p.N1436= on NM_033225.6) | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV59280823; called by muse, mutect2, varscan2
- CSMD2 | c.243G>A p.S81= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs141030168; called by muse, mutect2, varscan2
- CUBN | c.10845C>T p.S3615= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs146137990; called by muse, mutect2, varscan2
- CYP19A1 | c.558C>T p.D186= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs767683305, COSV53057052; called by muse, mutect2
- DAB2IP | c.1785C>A p.I595= (on ENST00000408936; = p.I567= on NM_032552.3) | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV52254453; called by muse, mutect2, varscan2
- DCAF4L2 | c.861A>G p.S287= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV60476373; called by muse, mutect2, varscan2
- DNAI4 | c.1281T>C p.P427= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV64020680; called by muse, mutect2
- ERCC6L | c.1191G>A p.T397= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs776324309, COSV57819361; called by muse, mutect2, varscan2
- ERICH6 | c.693C>T p.F231= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs149996868; called by muse, mutect2
- EXTL1 | c.1578G>A p.T526= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as rs375085844; called by muse, mutect2, varscan2
- FAM122A | c.660C>T p.G220= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs1197798609, COSV55241230; called by muse, mutect2, varscan2
- FAM135B | c.3211T>C p.L1071= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV52704556; called by muse, mutect2
- FAM181A | c.558G>A p.Q186= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV50887815; called by muse, mutect2, varscan2
- FASTKD2 | c.1542T>A p.A514= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV52697356; called by muse, mutect2, varscan2
- FAT4 | c.12177A>T p.G4059= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs1415033092, COSV58671384; called by muse, mutect2, varscan2
- FCRL5 | c.1695C>T p.R565= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs1259561812, COSV62511393; called by muse, mutect2, varscan2
- FICD | c.909C>T p.P303= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs750760178, COSV57205319; called by muse, mutect2, varscan2
- FOCAD | c.2268C>T p.G756= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV58093356; called by muse, mutect2, varscan2
- GALNT13 | c.255T>C p.L85= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV67209767; called by muse, mutect2, varscan2
- GDF2 | c.291G>A p.T97= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs782438337; called by muse, mutect2, varscan2
- GRIK4 | c.2226C>T p.G742= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs913786187, COSV70799735; called by muse, mutect2
- IK | c.1227C>A p.S409= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV64225561, COSV64226500; called by muse, mutect2
- INTS14 | c.513C>T p.C171= (on ENST00000313182 / NM_001366360.2; = p.C92= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV57525651; called by muse, mutect2, varscan2
- ITIH5 | c.2514C>T p.C838= | Silent (SNP) | VAF 7/162 reads (4%) | catalogued as COSV53659712, COSV99903597; called by muse, mutect2
- ITPR2 | c.2826C>T p.S942= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as rs547097786, COSV67264432; called by muse, mutect2, varscan2
- ITPR2 | c.1074G>A p.P358= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs201250480, COSV67264437; called by muse, mutect2, varscan2
- JAKMIP1 | c.1296G>A p.P432= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs766668456, COSV51522052; called by muse, mutect2, varscan2
- KCND3 | c.1911C>T p.G637= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV56174829; called by muse, mutect2, varscan2
- KIRREL3 | c.2199C>T p.S733= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs1418372531, COSV69383660; called by muse, mutect2, varscan2
- KL | c.606C>T p.D202= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV66307793; called by muse, mutect2
- KLHDC3 | c.204G>A p.G68= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV55063506; called by muse, mutect2, varscan2
- KRT1 | c.1782C>T p.G594= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1161223903, COSV52864853; called by muse, mutect2
- LGALS14 | c.135T>C p.D45= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV62372158; called by muse, mutect2, varscan2
- LRIT2 | c.1542G>A p.P514= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as rs907196641, COSV60559467; called by muse, mutect2, varscan2
- LRRC15 | c.552C>T p.S184= | Silent (SNP) | VAF 42/365 reads (12%) | catalogued as rs779197120, COSV61649450; called by muse, mutect2, varscan2
- MAN1A2 | c.399T>C p.I133= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV62976197; called by muse, mutect2, varscan2
- MED19 | c.357T>C p.P119= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV54704973; called by muse, mutect2, varscan2
- MIDEAS | c.1221G>A p.S407= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs142510283; called by muse, mutect2, varscan2
- MIS18A | c.45C>T p.G15= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs1441564293, COSV51588556; called by muse, mutect2, varscan2
- MPDZ | c.3834C>T p.A1278= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs376910378; called by muse, mutect2, varscan2
- MUC16 | c.6642T>C p.N2214= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV67444250; called by muse, mutect2, varscan2
- MUC17 | c.7632T>C p.S2544= | Silent (SNP) | VAF 79/566 reads (14%) | catalogued as COSV60279793; called by muse, mutect2, varscan2
- MUC5B | c.9393G>A p.T3131= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as rs778855110, COSV71589943; called by muse, mutect2, varscan2
- MUC5B | c.11220C>T p.T3740= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs761306783, COSV71594036; called by muse, mutect2, varscan2
- MYSM1 | c.1920C>A p.A640= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV68976928; called by muse, mutect2, varscan2
- N4BP1 | c.1674C>T p.C558= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as COSV52209457; called by muse, mutect2, varscan2
- NTF3 | c.345G>A p.P115= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as rs772851614, COSV58417151; called by muse, mutect2
- OBI1 | c.837C>T p.G279= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs934132761, COSV56144454; called by muse, mutect2, varscan2
- PARVB | c.354C>T p.G118= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as COSV58683851; called by muse, mutect2, varscan2
- PDZRN4 | c.2670G>A p.K890= (on ENST00000402685 / NM_001164595.2; = p.K632= on NM_013377.4) | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs1298024134, COSV54191851; called by muse, mutect2
- PIK3C2A | c.849T>C p.N283= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV56400304; called by muse, mutect2, varscan2
- PITPNM3 | c.1377C>T p.S459= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs143785279; called by mutect2, varscan2
- PLCH1 | c.2865C>T p.G955= (on ENST00000340059 / NM_001130960.2; = p.G947= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs1471947993, COSV58185094; called by muse, mutect2, varscan2
- PLPPR2 | c.60C>T p.F20= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs200589087, COSV52258538; called by muse, mutect2, varscan2
- PLXNB2 | c.1506G>A p.P502= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs780878945, COSV63780042; called by muse, mutect2, varscan2
- POGLUT2 | c.882G>A p.T294= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs1267596670, COSV65682740; called by muse, mutect2, varscan2
- POLE | c.666C>T p.R222= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs1357052511, COSV57674047; ClinVar: uncertain significance; called by muse, mutect2
- PRG4 | c.3714A>T p.G1238= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV63354910; called by muse, mutect2
- PTGFRN | c.1881C>T p.G627= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs779715817, COSV67797687; called by muse, mutect2
- RALGAPA1 | c.1747C>T p.L583= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV51876463; called by muse, mutect2
- RCE1 | c.909G>A p.T303= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs753713165, COSV58992017; called by muse, mutect2, varscan2
- RHOD | c.534C>T p.N178= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs759025110, COSV58211078; called by muse, mutect2
- RNF216 | c.1770C>T p.A590= (on ENST00000425013 / NM_207116.3; = p.A647= on NM_207111.4) | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs200434435, COSV66289005; called by muse, mutect2, varscan2
- ROBO1 | c.4917A>G p.G1639= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV71391600; called by muse, mutect2, varscan2
- RPA1 | c.1122C>T p.P374= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs775451626, COSV54607181; called by muse, mutect2, varscan2
- RYR3 | c.1570C>T p.L524= | Silent (SNP) | VAF 10/149 reads (7%) | catalogued as COSV66777529; called by muse, mutect2
- SATL1 | c.30C>T p.G10= (on ENST00000395409; = p.G197= on NM_001012980.2) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60575403; called by muse, mutect2, varscan2
- SFRP2 | c.150C>T p.C50= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV56836738; called by muse, mutect2
- SLC14A2 | c.2574G>A p.P858= | Silent (SNP) | VAF 34/536 reads (6%) | catalogued as rs567587864, COSV54906106; called by muse, mutect2
- SLC17A9 | c.1170C>T p.G390= | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as rs755997098, COSV64846793; called by muse, mutect2
- SLC22A1 | c.87G>A p.S29= | Silent (SNP) | VAF 30/204 reads (15%) | catalogued as rs760852994, COSV61451536; called by muse, mutect2, varscan2
- SLC2A14 | c.741G>A p.T247= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs756918734, COSV61585491; called by muse, mutect2, varscan2
- SPAM1 | c.6A>T p.G2= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV56141143; called by muse, mutect2
- SUFU | c.123C>T p.C41= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1412892420, COSV64013846; ClinVar: likely benign; called by muse, mutect2
- SYNE2 | c.16407G>A p.P5469= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as rs755327532, COSV59939462; called by muse, mutect2, varscan2
- SYNGAP1 | c.2844C>T p.G948= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as rs753093321, COSV53378261; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYT10 | c.294G>A p.Q98= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV57337394; called by muse, mutect2, varscan2
- TAF12 | c.21A>G p.S7= | Silent (SNP) | VAF 20/154 reads (13%) | catalogued as COSV56039009; called by muse, mutect2, varscan2
- TF | c.1563C>T p.G521= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV53917631; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2085G>A p.A695= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs565390607, COSV51509905; called by mutect2, varscan2
- THSD4 | c.1431C>T p.G477= | Silent (SNP) | VAF 22/207 reads (11%) | catalogued as rs762593257, COSV55961031; called by muse, mutect2, varscan2
- TICRR | c.720C>T p.G240= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV51537776; called by muse, varscan2
- TLE4 | c.1233T>C p.A411= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs775123637, COSV54626175; called by muse, mutect2, varscan2
- TMED8 | c.813T>A p.G271= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV53625257; called by muse, mutect2, varscan2
- TRAPPC11 | c.2883A>G p.E961= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV58214479; called by muse, mutect2, varscan2
- TTL | c.891C>T p.S297= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as rs757506350, COSV51973201; called by muse, mutect2, varscan2
- UBASH3A | c.516C>T p.F172= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs750396374, COSV52310376, COSV52314801; called by muse, mutect2, varscan2
- UGT8 | c.138C>T p.H46= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs768880144, COSV100179055; called by muse, mutect2, varscan2
- UNC13B | c.2487C>T p.N829= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs762390942, COSV65931259; called by muse, mutect2, varscan2
- USP13 | c.2046C>T p.G682= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs771535175, COSV55862541; called by muse, mutect2, varscan2
- USP34 | c.9396C>T p.D3132= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as rs1166134734, COSV68397955; called by muse, mutect2
- ZBTB40 | c.3258G>A p.T1086= | Silent (SNP) | VAF 62/328 reads (19%) | catalogued as rs781407518, COSV65144578; called by muse, mutect2, varscan2
- ZNF214 | c.1380T>C p.H460= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV53480549; called by muse, mutect2, varscan2
- ZNF425 | c.693C>A p.S231= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV65200550; called by muse, mutect2, varscan2
- ZNF583 | c.1287T>G p.V429= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV52400957; called by muse, mutect2, varscan2
- ASIC2 | c.556-179683C>T | Intron (SNP) | VAF 10/56 reads (18%) | catalogued as rs1205956099, COSV99859566; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2702C>T | Intron (SNP) | VAF 25/196 reads (13%) | catalogued as COSV100153137; called by muse, mutect2, varscan2
- CTSL3P | n.220G>A | RNA (SNP) | VAF 10/87 reads (11%) | catalogued as rs756482365; called by muse, mutect2, varscan2
- CXCL12 | c.266+2635del | Intron (DEL) | VAF 31/182 reads (17%) | called by mutect2, pindel, varscan2
- FAM153CP | chr5:178055893 G>T | 3'Flank (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- FOLH1B | n.1795A>C | RNA (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457341 C>A | 5'Flank (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- MIR518A2 | n.14G>A | RNA (SNP) | VAF 44/258 reads (17%) | called by muse, mutect2, varscan2
- POLR2F | c.453-15189G>A | Intron (SNP) | VAF 16/70 reads (23%) | catalogued as rs779242826; called by muse, mutect2, varscan2
- SORCS1 | c.3371+190T>C | Intron (SNP) | VAF 25/151 reads (17%) | catalogued as COSV99544321; called by muse, mutect2, varscan2
